Somatic mutation profile of tumor specimen ALCH-B42U-TTP1-A (aliquot ALCH-B42U-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B42U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,337 days).
Specimen ALCH-B42U-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73c0a269-37c1-4b5e-b617-f405a2bdfe43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B42U-NB1-A (Blood Derived Normal), aliquot ALCH-B42U-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60f72475-82e7-4e56-80dc-f571ae25864c

The open-access MAF lists 211 somatic variants for this specimen: 139 protein-altering or splice-affecting, 44 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 44, Intron 16, 5'UTR 9, Nonsense Mutation 8, Frame Shift Del 4, Splice Region 3, 3'UTR 2, In Frame Del 1, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 57/360 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913315, CM991156, COSV58820621, COSV58820976, COSV99045288; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACSM1 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763519997; called by muse, mutect2, varscan2
- BCO2 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 31/412 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs138109510; called by muse, mutect2
- BRCA1 | c.3619A>G p.K1207E | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs80357455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64752578; called by muse, mutect2, varscan2
- CABP2 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs1217710255; called by muse, mutect2
- CACNA1F | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782241013, COSV59904429; ClinVar: uncertain significance; called by muse, mutect2
- CDK15 | c.1028C>T p.T343M (on ENST00000652192 / NM_001366386.2; = p.T292M on NM_139158.2) | Missense Mutation (SNP) | VAF 65/361 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as rs375122798; called by mutect2, varscan2
- CFAP46 | c.2201C>A p.A734E | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV63951418; called by muse, mutect2, varscan2
- CPXM2 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV99580736; called by muse, mutect2, varscan2
- DENND2B | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.761); catalogued as rs199731488; called by muse, varscan2
- DLX6 | c.804del p.N269Tfs*24 | Frame Shift Del (DEL) | VAF 43/328 reads (13%) | catalogued as COSV50295202, COSV99142336; called by mutect2, pindel, varscan2
- ELFN1 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs769042444, COSV70036232; called by muse, mutect2, varscan2
- ENPEP | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 49/286 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV54450264; called by muse, mutect2, varscan2
- FUCA1 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65692389; called by muse, mutect2, varscan2
- GCN1 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371279481; called by muse, mutect2
- GNA13 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs781422742; called by muse, mutect2, varscan2
- GPR83 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV54717591; called by muse, mutect2, varscan2
- GREB1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs192688544; called by muse, varscan2
- HOXD12 | c.304G>C p.A102P | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs558043201; called by muse, mutect2, varscan2
- INTS6 | c.892C>A p.L298I | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as rs1369191578; called by muse, mutect2
- IRX4 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV51472561; called by muse, mutect2
- KCNK1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64034562; called by muse, mutect2
- KIF23 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.995); catalogued as rs973478293, COSV52980821; called by muse, mutect2
- KRTAP13-1 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100819865, COSV62663087, COSV62663667; called by muse, mutect2, varscan2
- LIMCH1 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 45/214 reads (21%) | catalogued as COSV58274401; called by muse, mutect2, varscan2
- MBTPS2 | c.970+5G>A | Splice Region (SNP) | VAF 12/130 reads (9%) | catalogued as COSV63412572; called by muse, mutect2
- MET | c.3055G>A p.G1019S | Missense Mutation (SNP) | VAF 49/301 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs950642030; called by muse, mutect2, varscan2
- MIOS | c.2354G>T p.C785F | Missense Mutation (SNP) | VAF 65/435 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100402882; called by muse, mutect2, varscan2
- MS4A7 | c.118G>T p.G40W | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV55729076; called by muse, mutect2, varscan2
- MUC16 | c.36406G>A p.D12136N | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.058); catalogued as COSV67450360; called by muse, mutect2, varscan2
- MYF6 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 21/246 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV57351308, COSV57353722; called by muse, mutect2
- NINL | c.2999G>T p.R1000L | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV53999365; called by muse, mutect2, varscan2
- NLGN4X | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52024547, COSV99321006; called by muse, mutect2, varscan2
- NLRP8 | c.1965G>T p.L655F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99404758; called by muse, mutect2, varscan2
- NME8 | c.783G>T p.Q261H | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV99554092; called by muse, mutect2, varscan2
- NUP188 | c.3146A>G p.Y1049C | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs755404218; called by muse, mutect2, varscan2
- OR10AG1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs564411786, COSV56631895, COSV56632573; called by muse, mutect2
- OR11G2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs753341187; called by muse, mutect2, varscan2
- PBRM1 | c.2639del p.C880Sfs*35 | Frame Shift Del (DEL) | VAF 62/352 reads (18%) | catalogued as COSV56261911; called by mutect2, pindel, varscan2
- PDZRN3 | c.2296A>G p.S766G | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1273431378, COSV55208162; called by muse, mutect2, varscan2
- PRAMEF2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs757601936, COSV53575275; called by muse, mutect2
- SHANK3 | c.4139C>T p.S1380L | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771408069; called by muse, mutect2
- SHOX | c.824G>T p.S275I | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM119854, CX134686; called by muse, mutect2, varscan2
- SLC2A4 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as rs1567602787, COSV99076592; called by muse, mutect2, varscan2
- SPPL2C | c.1789C>A p.R597S | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs554288570, COSV100233904, COSV61292961; called by muse, mutect2, varscan2
- TBPL2 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 66/385 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs761446287, COSV55972986; called by muse, mutect2, varscan2
- TENM1 | c.4396G>T p.G1466C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64428595; called by muse, mutect2, varscan2
- WDFY4 | c.8131G>T p.G2711C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55424900; called by muse, mutect2, varscan2
- ZNF100 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99973657; called by mutect2, varscan2
- ZNF100 | c.1357G>C p.G453R | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); catalogued as rs758169696; called by muse, mutect2, varscan2
- ZNF43 | c.90G>T p.R30S | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61683466, COSV61685862; called by muse, mutect2, varscan2
- ADAMTS13 | c.2413C>T p.P805S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ADAMTS18 | c.983T>A p.L328Q | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS19 | c.2078C>A p.A693E | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.049); called by muse, mutect2
- ADAMTS6 | c.2783G>T p.R928M | Missense Mutation (SNP) | VAF 70/436 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ADGRA2 | c.1275G>C p.R425S | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.402); called by mutect2, varscan2
- ADGRF5 | c.3330G>T p.M1110I | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- AGT | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- AHNAK2 | c.520G>C p.A174P | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP6 | c.5834C>A p.S1945* | Nonsense Mutation (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.2172G>T p.R724S (on ENST00000361247 / NM_001162383.2; = p.R696S on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ART1 | c.853T>A p.C285S | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BCAN | c.1955C>A p.P652H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- BRD2 | c.1931A>C p.Y644S | Missense Mutation (SNP) | VAF 34/489 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- BRSK1 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- BTNL2 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 49/318 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- C12orf56 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCNB3 | c.1898A>T p.K633M | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CD244 | c.840G>C p.R280S (on ENST00000368033 / NM_001166663.2; = p.R275S on NM_016382.4) | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CDH12 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CDH24 | c.2344G>T p.G782C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CLDN2 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CNP | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CNTNAP2 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- COL4A2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 54/351 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CSF2RA | c.-27+1del | Splice Region (DEL) | VAF 25/173 reads (14%) | called by mutect2, pindel, varscan2
- CTNND1 | c.2140G>A p.A714T (on ENST00000399050 / NM_001085458.2; = p.A708T on NM_001331.3) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.371); called by mutect2, varscan2
- DGKQ | c.351G>C p.R117= | Splice Region (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- DNAH11 | c.7392G>T p.W2464C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUS3L | c.985del p.A329Rfs*3 | Frame Shift Del (DEL) | VAF 22/176 reads (13%) | called by pindel, varscan2
- DUSP22 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 26/351 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.585); called by muse, mutect2
- EEFSEC | c.1752T>A p.Y584* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2, varscan2
- ENPEP | c.1806A>T p.E602D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.055); called by muse, mutect2
- ERICH6B | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAM83B | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FKBPL | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- FXYD6 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- GABRB3 | c.1403G>T p.W468L | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GCC1 | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 41/247 reads (17%) | called by muse, mutect2, varscan2
- GNAQ | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- GPR37 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.03); called by muse, mutect2
- HDAC9 | c.1309A>T p.T437S | Missense Mutation (SNP) | VAF 55/425 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HNRNPL | c.1355G>T p.C452F | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGKV3D-7 | c.168C>A p.Y56* | Nonsense Mutation (SNP) | VAF 34/244 reads (14%) | called by muse, mutect2, varscan2
- IQGAP2 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- KAT6A | c.5818C>G p.P1940A | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNK18 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1549 | c.3749G>A p.R1250K | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRTAP6-2 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 31/221 reads (14%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- LRWD1 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MAGEB6B | c.161G>T p.R54M | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MCM5 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- MRC1 | c.1542C>A p.Y514* | Nonsense Mutation (SNP) | VAF 85/529 reads (16%) | called by muse, mutect2, varscan2
- MYNN | c.1489dup p.R497Kfs*16 | Frame Shift Ins (INS) | VAF 29/224 reads (13%) | called by mutect2, pindel, varscan2
- MYT1L | c.2929C>A p.P977T | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDE1 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NRBP1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.168); called by muse, mutect2
- NRXN3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PADI4 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- PARP12 | c.1978A>G p.I660V | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PCDHB16 | c.1507C>A p.L503M | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- PCDHB5 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 82/419 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCSK5 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE8B | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.17); called by muse, mutect2
- PEG3 | c.2806C>A p.R936S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHOX2B | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PLD3 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- PREPL | c.1299T>A p.H433Q | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PTPRH | c.2446A>C p.S816R | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PUS7 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- REM1 | c.591_601del p.D198Lfs*19 | Frame Shift Del (DEL) | VAF 30/215 reads (14%) | called by mutect2, pindel, varscan2
- RNF111 | c.2867+2T>C p.X956_splice (on ENST00000557998 / NM_001270530.1; = p.X948_splice on NM_017610.8 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2
- RNF31 | c.1062G>T p.W354C | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHOX | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A16 | c.1531A>T p.S511C | Missense Mutation (SNP) | VAF 95/586 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SLC6A5 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- SPICE1 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- SPTBN1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1828G>T p.A610S | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TNFSF12 | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TPTE | c.1149G>T p.Q383H (on ENST00000618007 / NM_199261.4; = p.Q365H on NM_199259.4) | Missense Mutation (SNP) | VAF 31/558 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2
- TTN | c.32603_32605del p.E10868del (on ENST00000591111; = p.E9941del on NM_133378.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 32/254 reads (13%) | called by pindel, varscan2
- TTR | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 108/687 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- UHRF1BP1L | c.1214A>T p.Q405L | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2
- XKR6 | c.1628C>G p.P543R | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ZKSCAN2 | c.1888A>G p.I630V | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF208 | c.1448G>C p.C483S | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AHCTF1 | c.5271C>T p.S1757= (on ENST00000366508; = p.S1731= on NM_015446.5) | Silent (SNP) | VAF 50/345 reads (14%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.1032C>T p.A344= | Silent (SNP) | VAF 33/170 reads (19%) | called by muse, mutect2, varscan2
- ALDH6A1 | c.57C>G p.S19= | Silent (SNP) | VAF 77/413 reads (19%) | called by muse, mutect2, varscan2
- APOB | c.12876C>A p.T4292= | Silent (SNP) | VAF 38/305 reads (12%) | catalogued as rs546024019, COSV51928988, COSV51942580; called by muse, mutect2, varscan2
- ARHGAP26 | c.429C>T p.G143= | Silent (SNP) | VAF 37/315 reads (12%) | called by muse, mutect2, varscan2
- DENND2B | c.6C>T p.T2= | Silent (SNP) | VAF 32/204 reads (16%) | called by muse, varscan2
- DNAH5 | c.3111C>T p.A1037= | Silent (SNP) | VAF 33/329 reads (10%) | catalogued as rs371824972, COSV99451118; called by muse, mutect2
- DYRK1B | c.1710C>T p.G570= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs966829857; called by muse, mutect2, varscan2
- EFCAB8 | c.2319C>A p.I773= | Silent (SNP) | VAF 63/326 reads (19%) | called by muse, mutect2, varscan2
- FGR | c.1329C>T p.S443= | Silent (SNP) | VAF 30/166 reads (18%) | called by muse, mutect2, varscan2
- GPR26 | c.867C>T p.S289= | Silent (SNP) | VAF 28/365 reads (8%) | catalogued as rs1420999713, COSV52933461; called by muse, mutect2
- HAVCR2 | c.51A>T p.L17= | Silent (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- HSD11B1 | c.27C>A p.L9= | Silent (SNP) | VAF 34/268 reads (13%) | catalogued as COSV54827506; called by muse, mutect2, varscan2
- IGKV1-27 | c.204C>T p.L68= | Silent (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2, varscan2
- ITGAX | c.2493C>T p.Y831= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs146985733; called by muse, mutect2, varscan2
- JPH2 | c.684C>T p.G228= | Silent (SNP) | VAF 91/174 reads (52%) | called by muse, mutect2, varscan2
- KRT25 | c.924C>G p.T308= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as rs764714874; called by muse, mutect2, varscan2
- LDHA | c.891G>A p.Q297= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV99908220; called by muse, mutect2, varscan2
- MAP4K3 | c.93C>T p.Y31= | Silent (SNP) | VAF 30/233 reads (13%) | called by muse, mutect2, varscan2
- MEFV | c.2325G>T p.V775= | Silent (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- MEGF10 | c.1575C>T p.C525= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs765445505; called by muse, mutect2
- MLLT6 | c.258G>T p.V86= | Silent (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.144G>T p.V48= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- MUC17 | c.10374T>C p.T3458= | Silent (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- MYOZ3 | c.657G>A p.P219= | Silent (SNP) | VAF 38/219 reads (17%) | catalogued as rs551161142; called by muse, mutect2, varscan2
- NPAS4 | c.768C>A p.P256= | Silent (SNP) | VAF 39/327 reads (12%) | called by muse, mutect2, varscan2
- NPW | c.45G>A p.P15= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2
- OR5V1 | c.456T>A p.G152= | Silent (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- OR6C1 | c.222C>A p.V74= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as COSV65572892; called by muse, mutect2, varscan2
- PDCD6IP | c.1983C>T p.D661= | Silent (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- PLEC | c.192C>G p.T64= | Silent (SNP) | VAF 52/657 reads (8%) | catalogued as COSV59622842; called by muse, mutect2
- PLEKHG2 | c.342A>G p.E114= | Silent (SNP) | VAF 19/138 reads (14%) | catalogued as COSV52691500; called by muse, mutect2, varscan2
- POM121L2 | c.1851C>A p.V617= | Silent (SNP) | VAF 42/143 reads (29%) | called by muse, mutect2, varscan2
- PPARA | c.396C>T p.L132= | Silent (SNP) | VAF 87/528 reads (16%) | catalogued as COSV53078921, COSV53080262; called by muse, mutect2, varscan2
- PTPRT | c.1707C>T p.S569= | Silent (SNP) | VAF 45/434 reads (10%) | catalogued as COSV62010976; called by muse, mutect2
- RSC1A1 | c.1761G>A p.L587= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as rs759562891; called by muse, mutect2
- SHOX | c.654C>A p.R218= | Silent (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- SIRPD | c.165T>C p.N55= | Silent (SNP) | VAF 55/320 reads (17%) | catalogued as rs1480306494, COSV67546821; called by muse, mutect2, varscan2
- SOS1 | c.2079T>C p.C693= | Silent (SNP) | VAF 74/570 reads (13%) | called by muse, mutect2, varscan2
- SPATA2 | c.1281A>C p.A427= | Silent (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- TTR | c.315C>A p.S105= | Silent (SNP) | VAF 108/688 reads (16%) | catalogued as rs11541787; called by muse, mutect2, varscan2
- TXK | c.1014C>A p.P338= | Silent (SNP) | VAF 34/265 reads (13%) | called by muse, mutect2, varscan2
- WNT7B | c.807G>C p.V269= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- ZNF575 | c.627G>A p.A209= | Silent (SNP) | VAF 46/297 reads (15%) | catalogued as rs774614626; called by muse, mutect2, varscan2
- ABCB8 | c.95+192A>T | Intron (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-38750del | Intron (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- AKNAD1 | c.1747-55C>T | Intron (SNP) | VAF 25/95 reads (26%) | catalogued as rs1011365440; called by muse, mutect2, varscan2
- CALD1 | c.71+23813_71+23814insT | Intron (INS) | VAF 14/126 reads (11%) | called by mutect2, varscan2
- COG4 | c.-10G>T | 5'UTR (SNP) | VAF 10/207 reads (5%) | catalogued as COSV56785262; called by muse, mutect2
- COX10 | c.-34G>T | 5'UTR (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2
- FAM170A | c.-9G>T | 5'UTR (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- GOLGA8J | c.591+277C>A | Intron (SNP) | VAF 38/274 reads (14%) | called by muse, mutect2, varscan2
- HDAC9 | c.-17C>A | 5'UTR (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- HSH2D | c.126-993G>T | Intron (SNP) | VAF 25/168 reads (15%) | called by muse, mutect2, varscan2
- IGKV2D-30 | c.-10C>T | 5'UTR (SNP) | VAF 48/209 reads (23%) | catalogued as rs745977826; called by muse, mutect2, varscan2
- KANSL2 | c.-9-159A>T | Intron (SNP) | VAF 37/159 reads (23%) | called by muse, mutect2, varscan2
- KIF5B | c.-33G>T | 5'UTR (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- NFE2L1 | c.-15T>A | 5'UTR (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- OFCC1 | n.2433G>A | RNA (SNP) | VAF 9/83 reads (11%) | catalogued as rs1190601374; called by muse, mutect2, varscan2
- PAX6 | c.358-11T>G | Intron (SNP) | VAF 84/522 reads (16%) | called by muse, mutect2, varscan2
- PITX2 | c.185-960C>A | Intron (SNP) | VAF 71/416 reads (17%) | called by muse, mutect2, varscan2
- PSG5 | c.431-2756T>A | Intron (SNP) | VAF 27/199 reads (14%) | catalogued as rs1480942137, COSV100742733; called by muse, mutect2, varscan2
- SPAG6 | c.121+22C>T | Intron (SNP) | VAF 39/174 reads (22%) | catalogued as rs376247326; called by muse, mutect2, varscan2
- SUN1 | c.659-289C>A | Intron (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- TGIF1 | c.183+37T>G | Intron (SNP) | VAF 50/187 reads (27%) | called by muse, mutect2, varscan2
- TNN | c.-85C>T | 5'UTR (SNP) | VAF 51/331 reads (15%) | called by muse, mutect2, varscan2
- TNNI2 | c.186+12T>C | Intron (SNP) | VAF 34/186 reads (18%) | catalogued as COSV53290700; called by muse, mutect2, varscan2
- TOP3B | c.384+57_384+58del | Intron (DEL) | VAF 29/316 reads (9%) | called by mutect2, pindel
- TOX2 | c.*227G>C | 3'UTR (SNP) | VAF 16/110 reads (15%) | catalogued as rs1040401494; called by muse, mutect2
- WDR25 | c.1413+74C>T | Intron (SNP) | VAF 11/50 reads (22%) | catalogued as rs1220378621; called by muse, mutect2, varscan2
- ZFP64 | c.*3G>T | 3'UTR (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- ZYG11A | c.-35G>T | 5'UTR (SNP) | VAF 27/135 reads (20%) | called by muse, mutect2, varscan2
